CCDI case PBCMIR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bf967243-20bd-42d7-985a-f2dfa8a636a0

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Choroid plexus carcinoma: ICD-O-3 morphology code: 9390/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.5 years (168 days).

Biospecimens (3 samples)
- Sample 0DV4IW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV4J8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DV4KZ: Tissue type: Tumor; Specimen type: Solid Tissue.
